Gene-level copy-number profile of tumor specimen C3N-02230-01 from CPTAC case C3N-02230, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.8 years (24,043 days).
Specimen C3N-02230-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c3b62180-f97e-4a1a-9de3-2ef66d2320f1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02230-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/d924f22f-bf57-4d28-af53-4739db9a10ab

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 26; copy number 2: 7,599; copy number 3: 10,303; copy number 4: 19,240; copy number 5: 7,739; copy number 6: 9,980; copy number 7: 2,460; copy number 8: 626; copy number 9: 424.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,306,469–69,358,177, 2 genes (within-gene range 0–1): AC114786.3, AC114786.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 424 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:101,034,868–134,713,049, 424 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 26. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
